Somatic mutation profile of tumor specimen MMRF_2331_1_BM_CD138pos (aliquot MMRF_2331_1_BM_CD138pos_T2_KHS5U_K14049) from MMRF case MMRF_2331, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,892 days).
Specimen MMRF_2331_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee7043be-1a7c-4601-a79b-c4a467c5e2ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2331_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2331_1_PB_Whole_C1_KHS5U_K14048; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b73b99d2-208f-4202-a684-3688363719c4

The open-access MAF lists 136 somatic variants for this specimen: 54 protein-altering or splice-affecting, 17 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 39, Intron 19, Silent 17, 5'UTR 3, 3'Flank 2, Splice Site 2, 5'Flank 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMIGO3 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 130/287 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1342562110; called by muse, mutect2, varscan2
- BEND3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100944616; called by muse, mutect2, varscan2
- CACNA1C | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.952); catalogued as rs1321643530; called by muse, mutect2, varscan2
- CHD6 | c.6013G>A p.E2005K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV64688777; called by muse, mutect2
- CSMD3 | c.2600C>G p.T867S (on ENST00000297405 / NM_001363185.1; = p.T763S on NM_052900.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52313944; called by muse, mutect2, varscan2
- CXCR3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1433273335; called by muse, mutect2, varscan2
- DOCK10 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs578072512; called by muse, mutect2, varscan2
- F2RL3 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs774704645; called by muse, mutect2, varscan2
- FAF2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56129835; called by muse, mutect2
- GFPT1 | c.1388G>A p.G463E (on ENST00000357308 / NM_001244710.2; = p.G445E on NM_002056.4) | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623046; called by muse, mutect2, varscan2
- GTPBP8 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55606554; called by muse, mutect2, varscan2
- HOXD9 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs1314534638; called by muse, mutect2, varscan2
- IGHV3-30 | c.234C>G p.Y78* | Nonsense Mutation (SNP) | VAF 133/751 reads (18%) | catalogued as rs774190079; called by muse, mutect2, varscan2
- IGLV3-1 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 99/102 reads (97%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs552062384; called by muse, mutect2, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, varscan2
- KATNB1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555579687, CM1412967, COSV65560145; called by muse, mutect2, varscan2
- KDM5C | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100949240, COSV64767770, COSV64771497; called by muse, mutect2
- LIMD1 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs748826383, COSV56268524; called by muse, mutect2, varscan2
- MAN2A1 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV54851088; called by muse, mutect2
- MYD88 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1337361092, COSV57182347; called by muse, mutect2
- NF1 | c.5268+1G>A p.X1756_splice (on ENST00000358273 / NM_001042492.3; = p.X1735_splice on NM_000267.3) | Splice Site (SNP) | VAF 66/123 reads (54%) | catalogued as CS000054, COSV104371687, COSV55985789; called by muse, mutect2, varscan2
- NUP98 | c.4250A>G p.N1417S (on ENST00000359171 / NM_001365126.1; = p.N1400S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747769050; called by muse, mutect2, varscan2
- PCDHA11 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV56513165; called by muse, mutect2, varscan2
- PCDHA12 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV56509785; called by muse, mutect2, varscan2
- PLEKHH2 | c.3887T>C p.I1296T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs771639817; called by muse, mutect2, varscan2
- SIGLEC1 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs373787879; called by muse, mutect2, varscan2
- SMAP2 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs756268696; called by muse, mutect2, varscan2
- TRIM71 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs1298443612; called by muse, mutect2, varscan2
- ARFGEF1 | c.1754A>C p.D585A | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC134 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- CELSR1 | c.7472G>A p.S2491N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CLDN34 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); called by mutect2, varscan2
- CMBL | c.271T>G p.W91G | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CXCL17 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DIS3 | c.1781A>C p.Q594P | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG1 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBRS | c.119C>T p.S40F (on ENST00000287468; = p.S560F on NM_001105079.3) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FEM1B | c.388T>A p.F130I | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GVQW3 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.308); called by muse, mutect2
- HIPK1 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- IRF4 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYMK | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- N4BP2L2 | c.1815A>T p.E605D (on ENST00000674422; = p.E176D on NM_033111.4) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NCAPD2 | c.1933A>G p.M645V | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- PCDH10 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PER3 | c.1195G>C p.D399H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIK3R1 | c.479A>C p.E160A | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POMT2 | c.924-1G>T p.X308_splice | Splice Site (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- RSBN1 | c.1878T>G p.D626E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SBF2 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A8 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC4A1 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TEX45 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ZNF416 | c.1420_1430del p.A474Qfs*3 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | called by pindel, varscan2
- ACD | c.835C>T p.L279= (on ENST00000620338; = p.L190= on NM_022914.3) | Silent (SNP) | VAF 22/215 reads (10%) | catalogued as rs774346517, COSV99537298; called by muse, mutect2, varscan2
- ANXA1 | c.333G>A p.L111= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV57410267; called by muse, mutect2, varscan2
- ARMCX5 | c.789T>G p.P263= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- CFAP65 | c.2535C>A p.G845= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100445833; called by muse, mutect2, varscan2
- CRB2 | c.882C>T p.G294= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as rs770808093; called by muse, mutect2, varscan2
- GBX2 | c.576G>A p.P192= | Silent (SNP) | VAF 38/410 reads (9%) | catalogued as rs757987864, COSV60444902; called by muse, mutect2
- GRIA1 | c.1071G>A p.E357= | Silent (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.156A>C p.G52= | Silent (SNP) | VAF 49/51 reads (96%) | catalogued as rs1232476476; called by muse, mutect2, varscan2
- METAP1 | c.1083C>T p.L361= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1037265839; called by muse, mutect2, varscan2
- MPPED1 | c.438C>T p.I146= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as rs369069551; called by muse, mutect2, varscan2
- PHF14 | c.2026C>A p.R676= | Silent (SNP) | VAF 140/288 reads (49%) | catalogued as COSV101301812; called by muse, mutect2, varscan2
- PPP1R2 | c.282C>T p.A94= | Silent (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- RPS4X | c.321T>A p.G107= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
- SLC4A1 | c.501G>T p.L167= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- SYT16 | c.1368C>T p.L456= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- TTLL8 | c.1920C>T p.D640= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1380614684; called by muse, mutect2, varscan2
- WEE1 | c.1095G>A p.A365= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs374597379; called by muse, mutect2, varscan2
- ACOX3 | c.1829-71C>A | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- AFDN | chr6:167971821 A>T | 3'Flank (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- AFF1 | chr4:87006886 G>A | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as rs1348318931; called by muse, mutect2, varscan2
- ALDH1L1 | c.2653+129C>T | Intron (SNP) | VAF 55/102 reads (54%) | catalogued as rs777621763, COSV56419586; called by muse, mutect2, varscan2
- ALS2 | c.*630G>T | 3'UTR (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- ARGLU1 | c.*1351T>A | 3'UTR (SNP) | VAF 34/36 reads (94%) | called by muse, mutect2, varscan2
- ARGLU1 | c.*1350A>T | 3'UTR (SNP) | VAF 33/35 reads (94%) | called by muse, mutect2, varscan2
- ASAH1 | c.126+441G>A | Intron (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- ATP6V0A2 | c.1039-95A>C | Intron (SNP) | VAF 15/27 reads (56%) | catalogued as rs978941122, COSV100376923; called by muse, mutect2, varscan2
- C4orf46 | c.*86G>A | 3'UTR (SNP) | VAF 149/319 reads (47%) | called by muse, mutect2, varscan2
- CNIH4 | c.*1376T>A | 3'UTR (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- CORO1C | c.*1083C>A | 3'UTR (SNP) | VAF 67/147 reads (46%) | called by muse, mutect2, varscan2
- CRB1 | c.3879-497T>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- CSRNP3 | c.*6946G>T | 3'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- DDI1 | c.*111C>A | 3'UTR (SNP) | VAF 97/188 reads (52%) | catalogued as COSV100158617; called by muse, mutect2, varscan2
- DENND5A | c.1907-1194_1907-1189delinsCCCCGGGCGGGAAA | Intron (INS) | VAF 33/92 reads (36%) | called by pindel, varscan2*
- EIF5 | c.*3450T>C | 3'UTR (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- ELOA | c.*830C>T | 3'UTR (SNP) | VAF 10/78 reads (13%) | catalogued as rs1379102086; called by muse, mutect2, varscan2
- EPOP | c.*1362G>A | 3'UTR (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- FAM8A1 | c.*375G>A | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs200864954; called by muse, varscan2
- FGFR3 | chr4:1807287 G>A | 3'Flank (SNP) | VAF 9/66 reads (14%) | called by muse, varscan2
- FUT6 | c.*61G>A | 3'UTR (SNP) | VAF 325/501 reads (65%) | catalogued as rs944024494; called by muse, mutect2, varscan2
- GIPC2 | c.*1374C>A | 3'UTR (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- GPD1L | c.*2340T>A | 3'UTR (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- GPR158 | c.*272G>T | 3'UTR (SNP) | VAF 59/99 reads (60%) | called by muse, mutect2, varscan2
- KCNK2 | c.*1465dup | 3'UTR (INS) | VAF 51/124 reads (41%) | catalogued as rs1313080554; called by mutect2, pindel, varscan2
- LPP | c.*12939G>T | 3'UTR (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- MCMDC2 | c.1769+286T>A | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- METTL17 | c.529-53G>A | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MINK1 | c.2565-158G>A | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- NABP1 | c.*1407C>G | 3'UTR (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.704G>A | RNA (SNP) | VAF 10/349 reads (3%) | called by muse, mutect2
- NOS1 | c.*1768G>A | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- NUDC | c.742-23C>G | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- OR2C3 | c.*4585C>A | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, varscan2
- OSBPL6 | c.*223A>T | 3'UTR (SNP) | VAF 30/182 reads (16%) | called by muse, varscan2
- OSBPL6 | c.*224A>T | 3'UTR (SNP) | VAF 38/180 reads (21%) | called by muse, varscan2
- PELI1 | c.*1630A>G | 3'UTR (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- PIP4K2A | c.*155A>G | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- PPP1R14B | c.-259_-258del | 5'UTR (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- PPP1R32 | c.1044-111T>A | Intron (SNP) | VAF 44/77 reads (57%) | catalogued as rs751845789; called by muse, mutect2, varscan2
- PRMT8 | c.418-1066C>T | Intron (SNP) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- PRSS40A | n.318-668C>G | Intron (SNP) | VAF 10/73 reads (14%) | called by mutect2, varscan2
- RBM24 | c.348-895T>C | Intron (SNP) | VAF 139/362 reads (38%) | called by muse, varscan2
- RBM24 | c.348-894G>T | Intron (SNP) | VAF 138/362 reads (38%) | called by muse, varscan2
- RELN | c.-151G>C | 5'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- RETNLB | c.*71T>A | 3'UTR (SNP) | VAF 12/408 reads (3%) | called by muse, mutect2
- RPL37 | c.*2199T>G | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- SCN9A | c.*1257G>A | 3'UTR (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- SCNN1B | c.*227T>A | 3'UTR (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
- SESTD1 | c.1647+53C>T | Intron (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- SH3D21 | c.*59C>G | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- SLC22A15 | c.*557A>G | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.*706G>A | 3'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- SNN | c.*1827A>G | 3'UTR (SNP) | VAF 76/135 reads (56%) | called by muse, mutect2, varscan2
- STARD8 | c.*199C>T | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- STUM | c.*7107A>G | 3'UTR (SNP) | VAF 5/82 reads (6%) | catalogued as rs935402754; called by muse, mutect2
- THY1 | c.*407G>A | 3'UTR (SNP) | VAF 55/328 reads (17%) | called by muse, mutect2, varscan2
- TMEM184C | c.-44C>T | 5'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- TRIM8 | c.*1124T>A | 3'UTR (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- U2SURP | c.*2119G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- UBE2N | c.*363_*367dup | 3'UTR (INS) | VAF 89/312 reads (29%) | catalogued as rs527860095; called by mutect2, varscan2
- UBXN6 | c.1052-18G>A | Intron (SNP) | VAF 6/160 reads (4%) | called by muse, mutect2
- WRAP73 | c.516+58G>A | Intron (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- XKR6 | c.764+5516T>A | Intron (SNP) | VAF 152/311 reads (49%) | called by muse, mutect2, varscan2
